Somatic mutation profile of tumor specimen TCGA-MP-A4TE-01A (aliquot TCGA-MP-A4TE-01A-22D-A25L-08) from TCGA case TCGA-MP-A4TE, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.5 years (20,627 days).
Specimen TCGA-MP-A4TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09f954ab-0a5a-4615-8a18-06a435bba86c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TE-10A (Blood Derived Normal), aliquot TCGA-MP-A4TE-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e39fc5e4-1189-43d4-ae37-755097be758b

The open-access MAF lists 153 somatic variants for this specimen: 113 protein-altering or splice-affecting, 32 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 32, Frame Shift Del 5, Nonsense Mutation 5, Frame Shift Ins 3, RNA 3, Splice Site 2, Intron 2, Translation Start Site 2, 3'UTR 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 32/58 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 24/30 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981868, COSV58822591, COSV58830751; called by muse, mutect2, varscan2
- ADCY2 | c.781A>C p.I261L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100602442; called by muse, mutect2, varscan2
- AMOTL1 | c.2333A>C p.K778T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100504321; called by muse, mutect2, varscan2
- ART5 | c.679dup p.H227Pfs*2 | Frame Shift Ins (INS) | VAF 36/142 reads (25%) | catalogued as rs748137393; called by mutect2, varscan2
- CADPS | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1214963810, COSV99337214; called by muse, mutect2, varscan2
- CAPSL | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 49/104 reads (47%) | catalogued as rs1422705433, COSV101274232, COSV68439092; called by muse, mutect2, varscan2
- CD163L1 | c.1454G>C p.C485S | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143303315, COSV100549923; called by muse, mutect2, varscan2
- CDK11A | c.1883G>T p.G628V (on ENST00000378633 / NM_001313896.2; = p.G625V on NM_024011.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99319231; called by muse, mutect2, varscan2
- CFAP47 | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 41/57 reads (72%) | catalogued as COSV52883816, COSV52888611; called by muse, mutect2, varscan2
- CFAP65 | c.5101G>C p.V1701L | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV100444930, COSV100445941; called by muse, mutect2, varscan2
- CFHR3 | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.268); catalogued as COSV100807492; called by muse, mutect2, varscan2
- CLCA4 | c.2698C>G p.L900V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100991094; called by muse, mutect2, varscan2
- CNTN3 | c.776T>A p.I259N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99723987; called by muse, mutect2, varscan2
- CNTNAP5 | c.1349G>T p.W450L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101443315; called by muse, mutect2, varscan2
- COL11A1 | c.3298C>A p.P1100T | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100615900, COSV62184538; called by muse, mutect2, varscan2
- COL4A5 | c.3938G>T p.R1313L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV100087309, COSV60360107; called by muse, mutect2, varscan2
- CPA4 | c.1256A>T p.N419I | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV99744850; called by muse, mutect2, varscan2
- CYC1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100010319; called by muse, mutect2, varscan2
- CYP11B2 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs776680043, COSV100010907, COSV59994558; called by muse, mutect2, varscan2
- CYP39A1 | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99242115; called by muse, mutect2
- DDX10 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100489296; called by muse, mutect2, varscan2
- DDX25 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371417545; called by muse, mutect2, varscan2
- DNAH17 | c.2636G>C p.R879P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.484); catalogued as COSV101101931; called by muse, mutect2, varscan2
- DOCK6 | c.1475T>A p.V492E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV99370917; called by muse, mutect2, varscan2
- DVL3 | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs1295916129, COSV99490491, COSV99490647; called by muse, mutect2, varscan2
- DYSF | c.3115C>T p.R1039W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760443264, COSV99245862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EML5 | c.2243G>C p.G748A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100715367; called by muse, mutect2, varscan2
- ERC1 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 102/177 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV100705847; called by muse, mutect2, varscan2
- FAM122B | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53230825, COSV53230933; called by muse, mutect2, varscan2
- FAM126A | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV101327101; called by muse, mutect2, varscan2
- FAM166A | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100457836; called by muse, mutect2
- FAM71C | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV100175713; called by muse, mutect2, varscan2
- FAM83C | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs866205426, COSV65583734; called by muse, mutect2, varscan2
- FMN2 | c.2636C>A p.P879Q | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100144403; called by muse, mutect2, varscan2
- FOXA3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56215364; called by muse, mutect2, varscan2
- FXYD1 | c.-2C>A | Splice Region (SNP) | VAF 48/77 reads (62%) | catalogued as COSV99544803; called by muse, mutect2, varscan2
- GALNT15 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327502, COSV60216550; called by muse, mutect2, varscan2
- GK2 | c.1637C>A p.A546E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100725916; called by muse, mutect2, varscan2
- GLIPR1 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99875614; called by muse, mutect2, varscan2
- GPLD1 | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs112686285; called by muse, mutect2, varscan2
- GPR155 | c.861-1G>T p.X287_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99789795; called by muse, mutect2, varscan2
- HAS2 | c.400T>A p.F134I | Missense Mutation (SNP) | VAF 59/510 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100391635; called by muse, mutect2, varscan2
- HDLBP | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV100190281; called by muse, mutect2, varscan2
- HPSE | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV100264259; called by muse, mutect2, varscan2
- IARS2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228224; called by muse, mutect2, varscan2
- IRF2BPL | c.2026A>G p.N676D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV99467966; called by muse, mutect2, varscan2
- ITGAV | c.2273C>A p.P758Q | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); catalogued as COSV99654637; called by muse, mutect2, varscan2
- KIF2B | c.1792G>T p.V598F | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as rs1403265582, COSV99275090; called by muse, mutect2
- KLHL21 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs147251785, COSV100887215; called by muse, mutect2, varscan2
- KREMEN1 | c.413C>T p.T138M (on ENST00000407188; = p.T140M on NM_032045.5) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1440967211, COSV100588643; called by muse, mutect2, varscan2
- LIN9 | c.998G>A p.G333E (on ENST00000366808 / NM_001270410.2; = p.G278E on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100067277; called by muse, mutect2, varscan2
- LRP1 | c.5980C>T p.L1994F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99675392; called by muse, mutect2, varscan2
- LTBP1 | c.4307G>T p.C1436F (on ENST00000404816 / NM_206943.4; = p.C1110F on NM_000627.4) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99698071; called by muse, mutect2, varscan2
- MAGEB1 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100974915; called by muse, mutect2, varscan2
- MLLT3 | c.575G>C p.S192T | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as COSV100580862; called by muse, mutect2, varscan2
- MTA2 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.099); catalogued as COSV99545211; called by muse, mutect2, varscan2
- MTNR1B | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs745342258, COSV57066355; called by muse, mutect2, varscan2
- NFIC | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.143); catalogued as rs747005328, COSV100545220; called by muse, mutect2, varscan2
- NHS | c.4480G>T p.E1494* | Nonsense Mutation (SNP) | VAF 4/100 reads (4%) | catalogued as COSV101196514; called by muse, mutect2
- NHS | c.4481A>C p.E1494A | Missense Mutation (SNP) | VAF 4/99 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101196516; called by muse, mutect2
- NIT1 | c.132C>G p.C44W | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100919065; called by muse, mutect2, varscan2
- NKX2-4 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61085975; called by muse, mutect2, varscan2
- OR14A16 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100713740, COSV62927337; called by muse, mutect2, varscan2
- OR5J2 | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV100398965; called by muse, mutect2
- OR5W2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV60615646; called by muse, mutect2, varscan2
- OR6C6 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs530742573, COSV100626448; called by muse, mutect2, varscan2
- ORC6 | c.507dup p.A170Sfs*4 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs35441257; called by mutect2, varscan2
- OSBPL7 | c.2258C>A p.S753* | Nonsense Mutation (SNP) | VAF 111/189 reads (59%) | catalogued as COSV99136644; called by muse, mutect2, varscan2
- PCDH10 | c.2314G>T p.G772C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); catalogued as COSV99993327; called by muse, mutect2, varscan2
- PCDH15 | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV100218538, COSV57398543; called by muse, mutect2, varscan2
- PDCD6IP | c.2084T>A p.V695D | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100218705; called by muse, mutect2, varscan2
- PDZRN3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs762534324, COSV55193713; called by muse, mutect2, varscan2
- PLXNA4 | c.4130G>A p.S1377N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.925); catalogued as COSV100323588; called by muse, mutect2, varscan2
- PLXNA4 | c.2831G>T p.R944L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV100323287, COSV100323591; called by muse, mutect2, varscan2
- PPFIA3 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV61954641; called by muse, mutect2, varscan2
- PTPRE | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201268537; called by muse, mutect2, varscan2
- RABEP2 | c.942C>G p.D314E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.495); catalogued as COSV100706933; called by muse, mutect2, varscan2
- SAMSN1 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 36/57 reads (63%) | catalogued as COSV53468236, COSV99581182; called by muse, mutect2, varscan2
- SDCCAG8 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV59405067; called by muse, mutect2, varscan2
- SLC35D1 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as COSV99338105; called by muse, mutect2, varscan2
- SLIT1 | c.4540G>T p.D1514Y | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99821065; called by muse, mutect2, varscan2
- SOBP | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.905); catalogued as COSV100432993; called by muse, mutect2, varscan2
- SOGA3 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759687952, COSV64108326; called by muse, mutect2
- SYT15 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970294; called by muse, mutect2, varscan2
- TARS1 | c.1251-1G>C p.X417_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99465755; called by muse, mutect2, varscan2
- TLR4 | c.1117C>A p.P373T (on ENST00000355622 / NM_138554.5; = p.P333T on NM_003266.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV100842720; called by muse, mutect2, varscan2
- TMTC1 | c.1009G>T p.D337Y (on ENST00000539277 / NM_001193451.2; = p.D229Y on NM_175861.3) | Missense Mutation (SNP) | VAF 104/154 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99759294; called by muse, mutect2, varscan2
- TOP3B | c.1362G>C p.E454D | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs753337546, COSV100592446; called by muse, mutect2, varscan2
- TRPC4 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs780518092, COSV100156442; called by muse, mutect2, varscan2
- TTN | c.32308C>G p.P10770A (on ENST00000591111; = p.P9843A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | PolyPhen benign (0.003); catalogued as COSV100604290; called by mutect2, varscan2
- UNC13D | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs373721287; called by muse, mutect2
- WDR35 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV55605138; called by muse, mutect2, varscan2
- WDR36 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); catalogued as COSV72411314, COSV72411466; called by muse, mutect2, varscan2
- WWP1 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99616060; called by muse, mutect2, varscan2
- XIRP2 | c.3944C>A p.A1315D (on ENST00000628543; = p.A1490D on NM_152381.6) | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99741188; called by muse, mutect2, varscan2
- XRN1 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV99377693; called by muse, mutect2, varscan2
- ZBTB3 | c.1332C>G p.H444Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101188950; called by muse, mutect2, varscan2
- ZFHX4 | c.6800C>G p.T2267S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV99256486, COSV99260930; called by muse, mutect2, varscan2
- ZNF404 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.506); catalogued as COSV100182465; called by muse, mutect2, varscan2
- ZNF581 | c.501C>G p.H167Q | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99553088; called by muse, mutect2, varscan2
- B3GNT5 | c.946_956dup p.M319Ifs*5 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- F2RL2 | c.748_752del p.N250Lfs*39 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by pindel, varscan2*
- FRG2 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCM1 | c.-28_22del | Translation Start Site (DEL) | VAF 20/150 reads (13%) | called by mutect2, pindel
- KEAP1 | c.1810del p.V604Wfs*68 | Frame Shift Del (DEL) | VAF 104/188 reads (55%) | called by mutect2, pindel, varscan2
- MMP13 | c.1108del p.I370Yfs*13 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- OR51L1 | c.603del p.L202Ffs*3 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | called by mutect2, pindel, varscan2
- POTEA | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- POTEA | c.1339C>A p.Q447K (on ENST00000519951 / NM_001005365.2; = p.Q401K on NM_001002920.1) | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- RGS12 | c.1896del p.R633Gfs*43 | Frame Shift Del (DEL) | VAF 59/134 reads (44%) | called by mutect2, pindel, varscan2
- SGPP1 | c.774G>T p.L258= | Splice Region (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2
- SPATA31A1 | c.4037G>T p.G1346V | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB8 | c.1026G>C p.R342= (on ENST00000297504 / NM_001282291.2; = p.R325= on NM_007188.5) | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99874164; called by muse, mutect2, varscan2
- ABCC1 | c.2112C>T p.I704= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100579188; called by muse, mutect2, varscan2
- ACTN2 | c.1911T>G p.R637= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV100856704; called by muse, mutect2, varscan2
- CACNA1E | c.2913A>C p.P971= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100701899; called by muse, mutect2
- CCNB3 | c.3777C>A p.P1259= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99328811; called by muse, mutect2, varscan2
- CDH8 | c.2295C>A p.T765= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs546774504, COSV100180733; called by muse, mutect2, varscan2
- CHRNA1 | c.669C>A p.I223= (on ENST00000261007 / NM_001039523.3; = p.I198= on NM_000079.4) | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV99650315; called by muse, mutect2, varscan2
- CLK3 | c.1470G>A p.P490= (on ENST00000395066 / NM_001130028.1; = p.P342= on NM_003992.4) | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as rs143391795; called by muse, mutect2, varscan2
- CNTN1 | c.2625C>A p.T875= | Silent (SNP) | VAF 69/482 reads (14%) | catalogued as COSV100750972; called by muse, mutect2, varscan2
- COL20A1 | c.2727C>A p.P909= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100490264; called by muse, mutect2, varscan2
- CPVL | c.498C>T p.H166= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs761586784, COSV99605617; called by muse, mutect2, varscan2
- ELAC1 | c.144C>T p.S48= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99494851; called by muse, mutect2, varscan2
- FAM110B | c.723C>T p.A241= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as rs749004407, COSV64065272; called by muse, mutect2, varscan2
- FAM214B | c.1614C>G p.P538= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100521259, COSV100521293; called by muse, mutect2, varscan2
- JADE1 | c.1404C>T p.T468= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV56909875, COSV99885605; called by muse, mutect2, varscan2
- KRT86 | c.147C>T p.S49= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99524917; called by muse, mutect2, varscan2
- MATN4 | c.1269G>A p.T423= (on ENST00000372754; = p.T382= on NM_003833.4) | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV100636958; called by muse, mutect2, varscan2
- MBD2 | c.390G>A p.P130= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1407615954, COSV99840035; called by muse, varscan2
- MXRA5 | c.5880C>A p.V1960= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99476434; called by muse, mutect2, varscan2
- MYOG | c.669C>A p.P223= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99613894; called by muse, mutect2, varscan2
- NDRG4 | c.156G>A p.L52= (on ENST00000394282 / NM_001378332.1; = p.L32= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99261947; called by muse, mutect2, varscan2
- NELL1 | c.1965T>C p.S655= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs956193620, COSV100120430; called by muse, mutect2, varscan2
- PCDHA1 | c.1353C>T p.N451= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs143660641; called by muse, mutect2, varscan2
- PHEX | c.546G>A p.E182= | Silent (SNP) | VAF 151/190 reads (79%) | catalogued as COSV101039545; called by muse, mutect2, varscan2
- PRDM2 | c.3678C>T p.S1226= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as rs1234144606, COSV99341313; called by muse, mutect2, varscan2
- SEMA3G | c.2181G>A p.E727= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV99202285; called by muse, mutect2, varscan2
- SLC2A3 | c.318C>T p.C106= | Silent (SNP) | VAF 91/152 reads (60%) | catalogued as rs745443054, COSV50005059, COSV99306435; called by muse, mutect2, varscan2
- SLC44A2 | c.1326G>A p.L442= | Silent (SNP) | VAF 61/129 reads (47%) | catalogued as rs772921105, COSV100213105; called by muse, mutect2, varscan2
- TG | c.5790C>T p.D1930= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99600106; called by muse, mutect2, varscan2
- TRIM11 | c.894T>A p.P298= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99488250; called by muse, mutect2
- TTN | c.14607C>A p.T4869= (on ENST00000591111; = p.T3942= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV100601991; called by muse, mutect2, varscan2
- YME1L1 | c.874C>A p.R292= (on ENST00000326799 / NM_139312.3; = p.R235= on NM_014263.4) | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100463505, COSV58760127; called by muse, mutect2, varscan2
- AC073310.1 | n.975C>A | RNA (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622836 G>T | 3'Flank (SNP) | VAF 26/130 reads (20%) | catalogued as rs745864437, COSV100247032; called by muse, mutect2, varscan2
- CARD19 | c.*1242G>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as rs1426027848, COSV100968656; called by muse, mutect2, varscan2
- CBARP | c.1214+146G>A | Intron (SNP) | VAF 46/64 reads (72%) | catalogued as rs778716668, COSV53071131; called by muse, mutect2, varscan2
- DSCR4 | n.123G>T | RNA (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100077206, COSV100077375, COSV60300147; called by muse, mutect2, varscan2
- LPP | c.1114-19435C>T | Intron (SNP) | VAF 30/70 reads (43%) | catalogued as rs756836674, COSV100446669; called by muse, mutect2, varscan2
- MIR548I3 | n.129C>A | RNA (SNP) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- PAK5 | c.*2C>A | 3'UTR (SNP) | VAF 57/284 reads (20%) | catalogued as COSV62034481; called by muse, mutect2, varscan2
